TARGET case TARGET-15-SJMPAL040026 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/45de950e-210b-47c1-a953-cd7fd2d1c6bb

Demographics
Sex at birth: male; Age at index: 0 years; Vital status: Dead; Days to death: 30 days.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 0.5 years (182 days); Year of diagnosis: 2009; Days to last follow up: 30 days.

Follow-up (1 entry)
- Days to follow up: 30 days; Event-free: no event (relapse, second malignancy or death) recorded through day 30; Year of follow up: 2009.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0: Leukocytes 356 ×10³/µL.

Biospecimens (4 samples)
- Samples TARGET-15-SJMPAL040026-09A, TARGET-15-SJMPAL040026-09A.1, TARGET-15-SJMPAL040026-09A.2, TARGET-15-SJMPAL040026-09A.3 (4 with the same recorded description): Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Overall Survival Time in Days: 30
- Protocol: Japan (JACLS)
- WBC at Diagnosis: 355.5
- Initial Therapy: ALL
- Karyotype: 46,XY,t(14;15)(q32;q11.2-13) [4/20], 46,XY [16/20]
- WHO ALAL Classification: MLL
- WHO Dx: MLL
